Somatic mutation profile of tumor specimen ALCH-B1KC-TTP1-A (aliquot ALCH-B1KC-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1KC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.9 years (20,789 days).
Specimen ALCH-B1KC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f1f69fa-2c0f-4245-ba29-fb856c87822a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1KC-NB1-A (Blood Derived Normal), aliquot ALCH-B1KC-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b9bca8c-442d-4153-bef4-805eab0dbef2

The open-access MAF lists 66 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Frame Shift Del 5, Splice Site 4, RNA 3, Frame Shift Ins 3, Intron 2, 5'Flank 2, 5'UTR 2, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 112/401 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.1994A>C p.H665P | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.804); catalogued as rs772779797; called by muse, mutect2, varscan2
- ABCF2 | c.1449G>A p.M483I | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV55182940; called by muse, mutect2, varscan2
- DOCK10 | c.5990G>T p.C1997F | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as rs764406826; called by muse, mutect2, varscan2
- DUOX2 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237752365; called by muse, mutect2, varscan2
- ERCC4 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 95/356 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs753596005; called by muse, mutect2, varscan2
- FAM120B | c.911A>G p.Y304C | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53005246; called by muse, mutect2, varscan2
- MAMDC2 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 106/406 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65858957; called by muse, mutect2, varscan2
- SNX14 | c.2653+1G>T p.X885_splice (on ENST00000314673 / NM_001350535.1; = p.X832_splice on NM_020468.5 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 38/159 reads (24%) | catalogued as rs1404271469; called by muse, varscan2
- ALPK3 | c.2210G>A p.R737K | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CCNF | c.590_594+7del p.X197_splice | Splice Site (DEL) | VAF 24/171 reads (14%) | called by mutect2, pindel, varscan2
- CDH23 | c.5963T>A p.L1988Q | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CRABP2 | c.61A>C p.K21Q | Missense Mutation (SNP) | VAF 85/232 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- DNAH1 | c.4303C>A p.Q1435K | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DTX4 | c.1747G>A p.G583S | Missense Mutation (SNP) | VAF 104/357 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ESCO2 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 106/391 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- FTSJ1 | c.958-2A>C p.X320_splice | Splice Site (SNP) | VAF 98/344 reads (28%) | called by muse, mutect2, varscan2
- HNRNPK | c.1362-2_1362-1insAAAA p.X454_splice | Splice Site (INS) | VAF 31/121 reads (26%) | called by mutect2, pindel, varscan2
- IL20RA | c.1456dup p.T486Nfs*23 | Frame Shift Ins (INS) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- INAVA | c.1841T>C p.V614A | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ITGA4 | c.113C>A p.T38N | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ITIH6 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- KAT6B | c.4224_4225insCA p.E1409Qfs*53 | Frame Shift Ins (INS) | VAF 160/649 reads (25%) | called by mutect2, pindel, varscan2
- KIAA1210 | c.4430G>C p.G1477A | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRK2 | c.144_149delinsA p.E49Rfs*58 | Frame Shift Del (DEL) | VAF 60/488 reads (12%) | called by pindel, varscan2*
- NAV2 | c.869C>T p.A290V (on ENST00000396087 / NM_001244963.2; = p.A267V on NM_145117.5) | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NHSL1 | c.2326G>T p.V776F | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- NVL | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR11H4 | c.406A>T p.I136F | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PDE12 | c.310G>C p.G104R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP4R3B | c.1403_1407del p.N468Mfs*19 | Frame Shift Del (DEL) | VAF 17/118 reads (14%) | called by mutect2, pindel, varscan2
- PSMB8 | c.707_711dup p.R238Lfs*16 (on ENST00000374882 / NM_148919.4; = p.R234Lfs*16 on NM_004159.5) | Frame Shift Ins (INS) | VAF 69/325 reads (21%) | called by mutect2, pindel, varscan2
- RPP25 | c.527C>G p.P176R | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SLC15A5 | c.1521A>T p.L507F | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SMARCA4 | c.3681G>C p.K1227N | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SRRM5 | c.1226A>C p.K409T | Missense Mutation (SNP) | VAF 104/438 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- STK11 | c.836del p.G279Afs*8 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- SVEP1 | c.10141T>A p.S3381T | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- TRAT1 | c.335C>A p.S112* | Nonsense Mutation (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- UTRN | c.1928G>T p.G643V | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- VWA3B | c.3702del p.H1234Qfs*24 | Frame Shift Del (DEL) | VAF 41/162 reads (25%) | called by mutect2, pindel, varscan2
- WNK3 | c.5174C>T p.P1725L | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- XPO1 | c.665_666del p.V222Afs*21 | Frame Shift Del (DEL) | VAF 48/185 reads (26%) | called by mutect2, pindel, varscan2
- BRI3BP | c.381G>C p.L127= | Silent (SNP) | VAF 54/131 reads (41%) | called by muse, mutect2, varscan2
- CBWD6 | c.1056G>A p.E352= | Silent (SNP) | VAF 125/489 reads (26%) | called by muse, mutect2, varscan2
- CEP89 | c.1137G>A p.E379= | Silent (SNP) | VAF 61/289 reads (21%) | catalogued as COSV59866322; called by muse, mutect2, varscan2
- CUL9 | c.885G>A p.R295= | Silent (SNP) | VAF 61/236 reads (26%) | catalogued as rs1324370612; called by muse, mutect2, varscan2
- KIF16B | c.123A>G p.P41= | Silent (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- LRRK2 | c.1131C>G p.L377= | Silent (SNP) | VAF 98/347 reads (28%) | catalogued as COSV54150264; called by muse, mutect2, varscan2
- LTK | c.1332G>A p.G444= | Silent (SNP) | VAF 61/283 reads (22%) | called by muse, mutect2, varscan2
- MYO1A | c.123T>C p.I41= | Silent (SNP) | VAF 85/286 reads (30%) | catalogued as rs1264770023; called by muse, mutect2, varscan2
- NCKAP1L | c.2685G>T p.L895= | Silent (SNP) | VAF 67/258 reads (26%) | called by muse, mutect2, varscan2
- PI4KB | c.2217C>T p.A739= (on ENST00000368873 / NM_001369623.1; = p.A751= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 104/263 reads (40%) | catalogued as rs765958243; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1854A>T p.G618= | Silent (SNP) | VAF 66/227 reads (29%) | called by muse, mutect2, varscan2
- TMEM132D | c.2481C>A p.P827= | Silent (SNP) | VAF 11/202 reads (5%) | catalogued as COSV101243121; called by muse, mutect2
- UBXN8 | c.597C>G p.P199= | Silent (SNP) | VAF 71/271 reads (26%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149795 C>T | 5'Flank (SNP) | VAF 42/136 reads (31%) | catalogued as rs372988572; called by muse, mutect2, varscan2
- AC093642.3 | n.2693G>A | RNA (SNP) | VAF 131/504 reads (26%) | called by muse, varscan2
- AP000769.3 | chr11:65504424 G>A | 5'Flank (SNP) | VAF 77/295 reads (26%) | called by muse, mutect2, varscan2
- DZIP1L | c.2142+82G>T | Intron (SNP) | VAF 63/156 reads (40%) | called by muse, mutect2, varscan2
- FUT8 | c.-326+301_-326+306del | Intron (DEL) | VAF 58/232 reads (25%) | called by mutect2, pindel, varscan2
- HAUS2 | c.-2C>A | 5'UTR (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- NBPF22P | n.1189C>G | RNA (SNP) | VAF 105/464 reads (23%) | called by muse, mutect2, varscan2
- NXF5 | n.1115C>A | RNA (SNP) | VAF 105/540 reads (19%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157677 C>T | 3'Flank (SNP) | VAF 140/608 reads (23%) | catalogued as rs1331200449; called by muse, mutect2, varscan2
- TMC2 | c.-10G>A | 5'UTR (SNP) | VAF 84/279 reads (30%) | called by muse, mutect2, varscan2
